Somatic mutation profile of tumor specimen TCGA-A6-4107-01A (aliquot TCGA-A6-4107-01A-02D-1408-10) from TCGA case TCGA-A6-4107, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 57.7 years (21,064 days).
Specimen TCGA-A6-4107-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c72a30b7-53d3-43f6-8aee-4673c16adb5e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A6-4107-10A (Blood Derived Normal), aliquot TCGA-A6-4107-10A-01D-2188-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/70648f52-2c0a-447e-82c7-45f184b66cc3

The open-access MAF lists 200 somatic variants for this specimen: 146 protein-altering or splice-affecting, 47 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 131, Silent 47, Nonsense Mutation 7, RNA 4, Splice Site 3, Frame Shift Del 2, 3'UTR 2, Frame Shift Ins 2, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 70/118 reads (59%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 57/193 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PPP2R1A | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 19/31 reads (61%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519946, COSV59042187, COSV59042498; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCB8 | c.181C>T p.R61W (on ENST00000297504 / NM_001282291.2; = p.R44W on NM_007188.5) | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs765868774, COSV99874160; called by muse, mutect2, varscan2
- ADAMTS18 | c.1018G>A p.V340M | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.228); catalogued as rs1318904239, COSV51422920; called by muse, mutect2
- ADH1B | c.364G>A p.G122R | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100520801, COSV59294995; called by muse, mutect2
- AKAP12 | c.496C>A p.Q166K | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV99482946; called by muse, mutect2, varscan2
- AP1G1 | c.631C>T p.H211Y | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.144); catalogued as COSV100250265; called by muse, mutect2, varscan2
- ARHGAP35 | c.2044A>T p.R682* | Nonsense Mutation (SNP) | VAF 4/43 reads (9%) | catalogued as COSV101350887; called by muse, mutect2
- ARHGAP36 | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.921); catalogued as COSV99357543; called by muse, mutect2, varscan2
- ARHGEF10L | c.842C>T p.S281L | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.23); catalogued as rs763814803, COSV99392568; called by muse, mutect2, varscan2
- ATP8B2 | c.3499C>A p.Q1167K (on ENST00000672630; = p.Q1134K on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.693); catalogued as COSV63832133; called by muse, mutect2, varscan2
- B3GAT1 | c.269C>T p.T90M | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV56998311; called by muse, mutect2, varscan2
- BICC1 | c.2698G>A p.D900N | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1335975766, COSV100874811; called by muse, mutect2, varscan2
- BRWD3 | c.5144G>T p.G1715V | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.601); catalogued as COSV100955897; called by muse, mutect2, varscan2
- C16orf86 | c.907G>A p.V303I | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99708162; called by muse, varscan2
- C3 | c.442C>T p.R148W | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.638); catalogued as COSV55571762; called by muse, mutect2, varscan2
- CACNA2D1 | c.1720-1G>T p.X574_splice (on ENST00000356253 / NM_001366867.1; = p.X555_splice on NM_000722.4) | Splice Site (SNP) | VAF 26/247 reads (11%) | catalogued as COSV100666385; called by muse, mutect2
- CAMK2A | c.304G>A p.V102M | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV62246702; called by muse, mutect2, varscan2
- CAPN7 | c.1799C>T p.A600V | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as rs1294996382, COSV99512702; called by muse, mutect2, varscan2
- CC2D1A | c.2333G>A p.R778Q | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs981702503, COSV54310139, COSV99582967; called by muse, mutect2, varscan2
- CDH18 | c.995A>G p.K332R | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.029); catalogued as COSV56931715; called by muse, mutect2, varscan2
- CDH2 | c.447G>T p.K149N | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV99296393; called by muse, mutect2
- CHD4 | c.3542T>G p.L1181R (on ENST00000357008 / NM_001363606.2; = p.L1194R on NM_001273.5) | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV58903751, COSV58907878; called by mutect2, varscan2
- CLIP1 | c.1551A>T p.K517N (on ENST00000620786 / NM_001247997.1; = p.K506N on NM_002956.2) | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.423); catalogued as COSV100211501; called by muse, mutect2, varscan2
- CNTN1 | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs201037986, COSV61642012; called by muse, mutect2, varscan2
- COL11A1 | c.344T>A p.L115H | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62186809; called by muse, mutect2, varscan2
- COL22A1 | c.3502-1G>A p.X1168_splice | Splice Site (SNP) | VAF 5/27 reads (19%) | catalogued as COSV100277564; called by muse, mutect2
- COL6A3 | c.2755G>A p.A919T | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs114563217, COSV99797329; called by muse, mutect2, varscan2
- CSF2RB | c.169G>A p.V57I | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs368852888; called by muse, mutect2, varscan2
- CUBN | c.4621C>T p.R1541W | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs146824506; called by muse, mutect2, varscan2
- DNAH5 | c.3182T>C p.I1061T | Missense Mutation (SNP) | VAF 95/197 reads (48%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV99447886; called by muse, mutect2, varscan2
- DPYS | c.1359C>A p.F453L | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100679475, COSV60911365; called by muse, mutect2, varscan2
- ENPP5 | c.819G>C p.L273F | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.241); catalogued as COSV57909067; called by muse, mutect2, varscan2
- EPB41L1 | c.1600C>T p.R534W | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs375772370; called by muse, mutect2, varscan2
- EPHA2 | c.1847A>G p.Q616R | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as COSV100626065; called by muse, mutect2, varscan2
- FAM214A | c.692C>T p.T231I | Missense Mutation (SNP) | VAF 54/162 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs1477555311, COSV99957827; called by muse, mutect2, varscan2
- FAM214A | c.91C>T p.R31* | Nonsense Mutation (SNP) | VAF 19/56 reads (34%) | catalogued as COSV99957829; called by muse, mutect2, varscan2
- FAT2 | c.9557C>T p.T3186M | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as rs1220697824, COSV55824212; called by mutect2, varscan2
- FAT3 | c.8578G>A p.E2860K | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.72); PolyPhen benign (0.005); catalogued as rs765949446, COSV53120309; called by muse, mutect2, varscan2
- FGFR3 | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.605); catalogued as rs746415876, COSV99601350; called by muse, mutect2, varscan2
- FLT4 | c.3137C>T p.S1046L | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1460237997, COSV56097615; called by muse, mutect2, varscan2
- FNDC3B | c.3039C>A p.H1013Q | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.444); catalogued as COSV100393955; called by muse, mutect2, varscan2
- GMPPB | c.937C>T p.R313C | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as rs144421130; ClinVar: uncertain significance; called by mutect2, varscan2
- GPC3 | c.224G>C p.R75T | Missense Mutation (SNP) | VAF 17/232 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV100892914; called by muse, mutect2
- HCFC1 | c.4238C>A p.T1413K | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.015); catalogued as COSV60073759; called by muse, mutect2, varscan2
- IGLV2-23 | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.263); catalogued as rs557334938; called by muse, mutect2, varscan2
- IMMP2L | c.346G>A p.G116S | Missense Mutation (SNP) | VAF 45/86 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as COSV100069360; called by muse, mutect2, varscan2
- ITPKC | c.886G>A p.G296R | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.149); catalogued as COSV99648610; called by muse, mutect2, varscan2
- JAG1 | c.1394G>A p.R465Q | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as rs558315798, COSV99652684; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNG4 | c.1444G>A p.G482S | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs201015865, COSV100376978; called by muse, mutect2, varscan2
- KMT2D | c.14098G>A p.D4700N | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs369583907; called by muse, mutect2, varscan2
- KRT33B | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.351); catalogued as rs558957351, COSV52442349; called by muse, mutect2, varscan2
- KRTAP10-5 | c.788G>A p.R263H | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.04); catalogued as rs782773002, COSV100552744; called by muse, mutect2
- KSR2 | c.788G>A p.R263H | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.547); catalogued as rs779469526, COSV60369023; called by muse, mutect2
- LDHAL6B | c.718G>A p.G240R | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs753041468, COSV99895107; called by muse, mutect2, varscan2
- LENG8 | c.1388G>A p.R463Q | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); catalogued as rs1235639964, COSV58729808; called by muse, mutect2, varscan2
- LRRC8B | c.892G>C p.G298R | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100446393, COSV100446495; called by muse, mutect2, varscan2
- LRRK1 | c.5122A>T p.S1708C | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV99438936; called by muse, mutect2, varscan2
- MAP2 | c.3641C>A p.P1214H | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.947); catalogued as COSV99559100; called by muse, mutect2
- MCM6 | c.1949G>A p.R650Q | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs967390814, COSV99918916; called by muse, mutect2, varscan2
- MICAL1 | c.415G>A p.G139S | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); catalogued as rs777061783, COSV100668519; called by muse, mutect2, varscan2
- MX2 | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.009); catalogued as rs1383249450, COSV100415860; called by muse, mutect2, varscan2
- NEDD4 | c.3827C>T p.T1276I (on ENST00000508342 / NM_001284338.1; = p.T857I on NM_006154.4) | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs781704268, COSV100163583; called by muse, mutect2, varscan2
- NIPSNAP3A | c.147G>T p.M49I | Missense Mutation (SNP) | VAF 7/136 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.026); catalogued as rs1382595475, COSV66113473; called by muse, mutect2
- NKTR | c.1466C>T p.S489L | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99235528; called by muse, mutect2, varscan2
- NPAP1 | c.3057C>A p.S1019R | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.81); catalogued as COSV61511208; called by muse, mutect2, varscan2
- NRG3 | c.956G>T p.C319F | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64579786; called by muse, mutect2, varscan2
- NUP133 | c.2731C>T p.R911* | Nonsense Mutation (SNP) | VAF 20/134 reads (15%) | catalogued as rs748634904, COSV99772798; called by muse, mutect2, varscan2
- NYAP1 | c.827G>A p.R276Q | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.749); catalogued as rs772931629, COSV55720624; called by muse, mutect2, varscan2
- OBSCN | c.3914G>A p.R1305H | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as rs764909100, COSV99475983; called by muse, mutect2
- OBSCN | c.11063C>A p.A3688E | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV52849700; called by muse, mutect2, varscan2
- OPHN1 | c.388C>T p.R130W | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as COSV62783332; called by muse, mutect2, varscan2
- OR4C15 | c.693G>T p.M231I (on ENST00000314644; = p.M177I on NM_001001920.2) | Missense Mutation (SNP) | VAF 13/217 reads (6%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.005); catalogued as rs1397255363, COSV100115551, COSV58951531; called by muse, mutect2
- PATE2 | c.138G>T p.M46I | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.359); catalogued as COSV100653442; called by muse, mutect2, varscan2
- PCBP1 | c.299T>C p.L100P | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs1422143141, COSV57849655, COSV57849905, COSV57849936; called by muse, mutect2, varscan2
- PCBP3 | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV68408574; called by muse, mutect2, varscan2
- PCDHA3 | c.247A>G p.I83V | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.096); catalogued as rs1554121478, COSV100973768; called by muse, mutect2, varscan2
- PCDHGA6 | c.1102C>T p.L368F | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.521); catalogued as COSV99535104; called by muse, mutect2, varscan2
- PEAK1 | c.3542G>T p.C1181F | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.072); catalogued as COSV100432792; called by muse, mutect2, varscan2
- PEG3 | c.396C>T p.D132= | Splice Region (SNP) | VAF 6/38 reads (16%) | catalogued as rs761719508, COSV55624188; called by mutect2, varscan2
- PI4KA | c.1870G>A p.A624T | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99745463; called by muse, mutect2, varscan2
- PIBF1 | c.1273G>A p.V425M | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.944); catalogued as COSV58324482; called by muse, mutect2, varscan2
- PIK3C2B | c.3449C>T p.S1150L | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1427089698, COSV65814035; called by muse, mutect2, varscan2
- PLXND1 | c.3724G>A p.A1242T | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs140631068, COSV100140549; called by muse, mutect2, varscan2
- PPP1R3A | c.1946G>A p.S649N | Missense Mutation (SNP) | VAF 20/460 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52878369; called by muse, mutect2
- PREX1 | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.037); catalogued as rs145026241, COSV100906162; called by muse, mutect2
- PSMD6 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748146502, COSV55760294; called by muse, mutect2, varscan2
- PTGER2 | c.997C>T p.R333W | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as rs758324792, COSV55419234; called by muse, mutect2, varscan2
- PTPN23 | c.428C>T p.S143F | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55546178; called by muse, mutect2, varscan2
- PTPRN2 | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs751826612, COSV67023843, COSV67027410; called by muse, mutect2, varscan2
- PUM2 | c.532A>G p.S178G | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.209); catalogued as COSV100163437; called by muse, mutect2
- RHEX | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs782181485, COSV58980749; called by muse, mutect2, varscan2
- RIMS1 | c.1699T>A p.L567M | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV99325652; called by muse, mutect2
- RIMS1 | c.2324G>A p.G775E | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53457267; called by muse, mutect2, varscan2
- RNASEH2B | c.923A>C p.K308T | Missense Mutation (SNP) | VAF 78/182 reads (43%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as COSV100352291; called by muse, mutect2, varscan2
- RNF115 | c.747C>A p.F249L | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.09); catalogued as COSV100991679, COSV65165341; called by muse, mutect2
- RNF213 | c.328T>A p.L110M | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.419); catalogued as COSV100173334; called by muse, mutect2, varscan2
- RTL4 | c.76C>T p.R26W | Missense Mutation (SNP) | VAF 29/150 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as rs202145443, COSV61206399; called by muse, mutect2, varscan2
- SCN9A | c.2695A>T p.I899F (on ENST00000303354; = p.I888F on NM_002977.3) | Missense Mutation (SNP) | VAF 21/218 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs903068590, COSV100312217; called by muse, mutect2, varscan2
- SEC23A | c.1810C>T p.R604C | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1396481798, COSV56972208; called by muse, mutect2, varscan2
- SETX | c.7618C>T p.R2540* | Nonsense Mutation (SNP) | VAF 19/144 reads (13%) | catalogued as rs1369223474, COSV56384545; called by muse, mutect2, varscan2
- SLC17A1 | c.116G>A p.C39Y | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.926); catalogued as COSV99765685; called by muse, mutect2, varscan2
- SLC24A2 | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); catalogued as rs757988035, COSV53862991; called by muse, mutect2, varscan2
- SLC6A15 | c.1919G>A p.R640H | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as rs759917281, COSV57020143; called by muse, mutect2, varscan2
- SLFN5 | c.2549G>C p.G850A | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.674); catalogued as COSV100249623; called by mutect2, varscan2
- SLITRK1 | c.1865C>A p.P622Q | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as COSV100999885; called by muse, mutect2, varscan2
- SNCG | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.545); catalogued as COSV100813814; called by muse, mutect2, varscan2
- SPOCK2 | c.847C>T p.R283C | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760437901, COSV58034962, COSV58037708; called by muse, mutect2, varscan2
- SRSF4 | c.1243C>T p.R415W | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.328); catalogued as rs1244832348; called by muse, mutect2, varscan2
- STAB2 | c.2330T>C p.F777S | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV101185806; called by muse, mutect2, varscan2
- SYNE2 | c.12858T>G p.I4286M | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.184); catalogued as COSV100647319; called by muse, mutect2
- TAF1L | c.1894C>T p.R632W | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1206610807, COSV99644441; called by muse, varscan2
- TANGO2 | c.487C>A p.P163T | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59293100, COSV59294036; called by muse, mutect2, varscan2
- TDRKH | c.346C>T p.H116Y | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as COSV100917938; called by muse, mutect2, varscan2
- TGFB2 | c.831G>T p.K277N | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1304484008, COSV100860015; called by muse, mutect2, varscan2
- THAP5 | c.794A>G p.N265S (on ENST00000415914 / NM_001130475.3; = p.N223S on NM_182529.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/193 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0.028); catalogued as COSV99974448; called by muse, mutect2, varscan2
- TIAM1 | c.3152C>T p.T1051M | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54536943; called by muse, mutect2
- TIGAR | c.566T>G p.L189* | Nonsense Mutation (SNP) | VAF 13/94 reads (14%) | catalogued as COSV51628476; called by muse, mutect2, varscan2
- TLN2 | c.7166A>T p.Q2389L | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV100168634; called by muse, mutect2
- TMPRSS15 | c.2075G>A p.R692Q | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375777008; called by muse, mutect2, varscan2
- TSGA10 | c.992G>A p.R331Q | Missense Mutation (SNP) | VAF 9/130 reads (7%) | SIFT tolerated (0.64); PolyPhen benign (0.056); catalogued as rs987272724, COSV100747486; called by muse, mutect2
- TTN | c.37849G>A p.V12617I (on ENST00000591111; = p.V5193I on NM_003319.4) | Missense Mutation (SNP) | VAF 23/129 reads (18%) | PolyPhen benign (0.183); catalogued as COSV100604256; called by muse, mutect2, varscan2
- TUBB4A | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.985); catalogued as rs1196637862, COSV51163156; called by muse, mutect2, varscan2
- U2AF1L4 | c.301G>A p.V101M (on ENST00000412391; = p.V62M on NM_144987.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs984081990, COSV99495052; called by muse, mutect2, varscan2
- UBE2J1 | c.373G>C p.G125R | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101470241, COSV70561788; called by mutect2, varscan2
- UNC5C | c.1666G>A p.A556T | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.805); catalogued as rs774698598, COSV101497849, COSV71659970; called by muse, mutect2, varscan2
- USP24 | c.3568G>A p.D1190N | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.452); catalogued as COSV53769478; called by muse, mutect2, varscan2
- XIRP2 | c.2759A>C p.K920T (on ENST00000628543; = p.K1095T on NM_152381.6) | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as COSV99741185; called by muse, mutect2, varscan2
- YME1L1 | c.311G>A p.R104H | Missense Mutation (SNP) | VAF 23/202 reads (11%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs746220580, COSV100463504; called by muse, mutect2, varscan2
- ZBED9 | c.1362G>T p.W454C | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs745568755, COSV101509191, COSV101509307; called by muse, mutect2, varscan2
- ZIM2 | c.696A>T p.E232D | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.828); catalogued as COSV99688311; called by muse, mutect2, varscan2
- ZNF185 | c.1579G>A p.V527I | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as rs782134471; called by muse, mutect2
- ZNF385D | c.658G>T p.E220* | Nonsense Mutation (SNP) | VAF 6/61 reads (10%) | catalogued as COSV99874153; called by mutect2, varscan2
- ZNF483 | c.1837G>A p.G613R | Missense Mutation (SNP) | VAF 42/79 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1256723520, COSV58517348; called by muse, mutect2, varscan2
- ZNF493 | c.541A>G p.T181A | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.271); catalogued as COSV100828658; called by muse, mutect2, varscan2
- AKAP13 | c.1726G>T p.E576* | Nonsense Mutation (SNP) | VAF 5/58 reads (9%) | called by muse, mutect2
- GTF3C6 | c.604_605del p.E202Rfs*18 | Frame Shift Del (DEL) | VAF 18/130 reads (14%) | called by mutect2, pindel, varscan2
- H2AC6 | c.380C>A p.A127D | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); called by muse, mutect2
- OR6N1 | c.120G>T p.L40F | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- POF1B | c.386_387dup p.T130Lfs*12 | Frame Shift Ins (INS) | VAF 9/77 reads (12%) | called by mutect2, pindel
- POTEA | c.242C>A p.A81E | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.659); called by muse, mutect2, varscan2
- SND1 | c.2668-30_2668-1del p.X890_splice | Splice Site (DEL) | VAF 34/141 reads (24%) | called by mutect2, pindel, varscan2
- TSGA10 | c.1217A>C p.E406A | Missense Mutation (SNP) | VAF 9/184 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.133); called by muse, mutect2
- ZNF507 | c.2622dup p.L875Sfs*7 | Frame Shift Ins (INS) | VAF 9/67 reads (13%) | called by mutect2, pindel, varscan2
- ZNF804A | c.1802del p.K601Sfs*44 | Frame Shift Del (DEL) | VAF 25/92 reads (27%) | called by mutect2, pindel, varscan2
- ABCC4 | c.522T>A p.I174= | Silent (SNP) | VAF 10/67 reads (15%) | catalogued as COSV100972412; called by muse, mutect2, varscan2
- ADAMTS5 | c.273C>A p.V91= | Silent (SNP) | VAF 25/46 reads (54%) | catalogued as COSV99537379; called by muse, mutect2, varscan2
- ADAMTS9 | c.246C>A p.P82= | Silent (SNP) | VAF 23/132 reads (17%) | catalogued as COSV99899172; called by muse, mutect2, varscan2
- AGAP4 | c.603C>G p.T201= | Silent (SNP) | VAF 11/167 reads (7%) | called by muse, mutect2
- ASXL1 | c.621C>T p.S207= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as rs1228680740, COSV100038579; called by muse, mutect2, varscan2
- ATXN10 | c.1290C>T p.S430= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as COSV99426214; called by muse, mutect2, varscan2
- BEST1 | c.585G>A p.A195= | Silent (SNP) | VAF 5/49 reads (10%) | catalogued as rs776011957, COSV57121403; called by mutect2, varscan2
- BFAR | c.417G>A p.Q139= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as COSV99902136; called by muse, mutect2, varscan2
- C11orf42 | c.996C>T p.D332= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as rs146108977; called by muse, mutect2, varscan2
- C6orf118 | c.570C>T p.A190= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as rs756059342, COSV57813134; called by muse, mutect2, varscan2
- CFAP47 | c.132G>A p.P44= | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as COSV99934810; called by muse, mutect2, varscan2
- CHRNB4 | c.1275G>A p.Q425= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as rs1309982120, COSV99929285; called by muse, mutect2, varscan2
- CLEC4E | c.462C>T p.D154= | Silent (SNP) | VAF 33/59 reads (56%) | catalogued as rs375515544; called by muse, mutect2, varscan2
- DDX60L | c.2985A>G p.E995= | Silent (SNP) | VAF 30/123 reads (24%) | catalogued as COSV99487374; called by muse, mutect2, varscan2
- DSCAM | c.234C>T p.N78= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as rs770298655, COSV101258638, COSV68626120; called by muse, mutect2, varscan2
- EHD2 | c.957C>T p.P319= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as rs369898716, COSV99621838; called by muse, mutect2, varscan2
- EML4 | c.2391A>G p.R797= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV59300080; called by muse, mutect2, varscan2
- FAT2 | c.3324A>G p.L1108= | Silent (SNP) | VAF 27/107 reads (25%) | catalogued as COSV99942335; called by muse, mutect2, varscan2
- FBN3 | c.2613C>T p.N871= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as rs1242145856, COSV54453414; called by muse, mutect2, varscan2
- FLG | c.11427A>T p.A3809= | Silent (SNP) | VAF 82/223 reads (37%) | catalogued as COSV100911395; called by muse, mutect2, varscan2
- GABRE | c.402C>T p.N134= | Silent (SNP) | VAF 27/116 reads (23%) | catalogued as rs200914254, COSV64819963; ClinVar: likely benign; called by muse, mutect2, varscan2
- GFM1 | c.492C>T p.R164= | Silent (SNP) | VAF 26/71 reads (37%) | catalogued as COSV99962812; called by muse, mutect2, varscan2
- GPR161 | c.639C>T p.R213= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as rs759899756, COSV99606421; called by muse, mutect2, varscan2
- HTR1A | c.687G>A p.T229= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as COSV100108865, COSV60500045; called by muse, mutect2, varscan2
- IGHG4 | c.801G>A p.P267= | Silent (SNP) | VAF 26/546 reads (5%) | catalogued as rs369421878; called by muse, mutect2
- IGSF10 | c.6573A>G p.T2191= | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as rs1322879068, COSV99177504; called by muse, mutect2, varscan2
- KLHL34 | c.87C>T p.C29= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV65280183; called by muse, mutect2, varscan2
- L1CAM | c.2853C>T p.Y951= | Silent (SNP) | VAF 25/99 reads (25%) | catalogued as rs148187017, COSV100649014; ClinVar: likely benign; called by muse, mutect2, varscan2
- LBP | c.792T>C p.A264= | Silent (SNP) | VAF 12/101 reads (12%) | catalogued as COSV99460670; called by mutect2, varscan2
- MPDZ | c.3477C>T p.S1159= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as COSV100056515; called by muse, mutect2, varscan2
- MYO1H | c.1047G>A p.P349= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as rs773273078, COSV60447111; called by muse, mutect2, varscan2
- NGEF | c.1512C>T p.T504= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as rs755056921, COSV99888754; called by muse, mutect2, varscan2
- OR2G2 | c.264G>A p.L88= | Silent (SNP) | VAF 91/261 reads (35%) | catalogued as COSV100189686; called by muse, mutect2, varscan2
- OR5R1 | c.876A>G p.L292= | Silent (SNP) | VAF 11/101 reads (11%) | catalogued as COSV100393362; called by muse, mutect2, varscan2
- OR6C1 | c.744C>A p.I248= | Silent (SNP) | VAF 24/224 reads (11%) | catalogued as rs1458778859, COSV101110487, COSV65574638; called by muse, mutect2, varscan2
- OTOGL | c.1335C>T p.C445= (on ENST00000547103; = p.C436= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 30/111 reads (27%) | catalogued as rs776984171, COSV72005618; called by muse, mutect2, varscan2
- PCDH17 | c.1698C>T p.N566= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as COSV64976965; called by muse, mutect2, varscan2
- PCDHGB7 | c.2103G>T p.V701= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as COSV99535107; called by muse, mutect2, varscan2
- PDZD2 | c.6555G>A p.Q2185= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV99224540; called by muse, mutect2, varscan2
- PTPRO | c.2472C>T p.S824= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as rs752317809, COSV55522131; called by mutect2, varscan2
- REX1BD | c.222C>T p.R74= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV100678982; called by muse, mutect2, varscan2
- RPL19 | c.549G>A p.E183= | Silent (SNP) | VAF 13/106 reads (12%) | catalogued as COSV99841431; called by muse, mutect2, varscan2
- RYR2 | c.6822G>A p.L2274= | Silent (SNP) | VAF 31/306 reads (10%) | catalogued as COSV100769314; called by muse, mutect2, varscan2
- SHLD2 | c.1398C>T p.G466= | Silent (SNP) | VAF 95/228 reads (42%) | catalogued as COSV53956134; called by muse, mutect2, varscan2
- TPO | c.165C>T p.Y55= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as rs149346954, CM1510459, COSV61101360; ClinVar: likely benign; called by muse, mutect2, varscan2
- UHRF1 | c.1044C>T p.P348= (on ENST00000612630 / NM_001290050.1; = p.P361= on NM_013282.4) | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as rs1273174698, COSV99503424; called by muse, mutect2
- UMOD | c.1359C>T p.T453= | Silent (SNP) | VAF 23/45 reads (51%) | catalogued as rs144461487; called by muse, mutect2, varscan2
- AP003393.1 | n.983G>T | RNA (SNP) | VAF 13/24 reads (54%) | catalogued as rs750594983, COSV100405375; called by muse, mutect2, varscan2
- ARL14 | c.*1G>C | 3'UTR (SNP) | VAF 8/38 reads (21%) | catalogued as COSV100296458; called by mutect2, varscan2
- CCR7 | c.*2C>T | 3'UTR (SNP) | VAF 4/28 reads (14%) | catalogued as rs371882270; called by mutect2, varscan2
- DCHS2 | n.3510G>T | RNA (SNP) | VAF 6/130 reads (5%) | called by muse, mutect2
- DLG2 | c.205-65784C>T | Intron (SNP) | VAF 5/48 reads (10%) | catalogued as rs1272117491, COSV54644679; called by muse, mutect2, varscan2
- HERC2P3 | n.1393G>A | RNA (SNP) | VAF 5/18 reads (28%) | catalogued as rs763231386; called by muse, mutect2, varscan2
- MIR9-3 | n.60G>A | RNA (SNP) | VAF 11/47 reads (23%) | called by muse, mutect2, varscan2
